Somatic mutation profile of tumor specimen TCGA-FG-8182-01A (aliquot TCGA-FG-8182-01A-11D-2253-08) from TCGA case TCGA-FG-8182, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.5 years (12,972 days).
Specimen TCGA-FG-8182-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa0fd695-dd3d-4465-9ac0-c5c2dd09e2d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8182-10A (Blood Derived Normal), aliquot TCGA-FG-8182-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e6ad9c6-8eed-4584-829a-3eaac5187653

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 14, Silent 8, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 52/113 reads (46%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- BRD8 | c.1198A>G p.M400V (on ENST00000254900 / NM_139199.2; = p.M473V on NM_006696.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as COSV50145243; called by muse, mutect2, varscan2
- CCDC22 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782064535, COSV66050863; called by muse, mutect2
- CFAP61 | c.908A>T p.E303V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV55619656; called by muse, mutect2
- EXPH5 | c.4916G>A p.C1639Y | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.99); PolyPhen benign (0.077); catalogued as rs201764835, COSV56199014; called by muse, mutect2, varscan2
- FBXL18 | c.1495A>G p.M499V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.406); catalogued as rs778375443, COSV66107437; called by muse, mutect2, varscan2
- FERMT3 | c.1567C>T p.R523W (on ENST00000279227 / NM_178443.3; = p.R519W on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54177094; called by muse, mutect2
- IGFBP2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200421058, COSV52079502, COSV99288539; called by muse, mutect2, varscan2
- MUC16 | c.41754C>T p.T13918= | Splice Region (SNP) | VAF 15/141 reads (11%) | catalogued as rs755849764, COSV66689741; called by muse, mutect2, varscan2
- MYO3B | c.4009T>C p.S1337P | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV58694658; called by muse, mutect2, varscan2
- PADI3 | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.659); catalogued as rs770207385, COSV64933969; called by muse, mutect2
- PSG8 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV60609477; called by muse, mutect2
- RPL37A | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62897342; called by muse, mutect2
- TRPV6 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754442854, COSV63890566; called by muse, mutect2
- VSIG4 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs747618819, COSV66073183; called by muse, mutect2, varscan2
- ATRX | c.4785_4788dup p.G1597Yfs*5 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- ATRX | c.2093dup p.D699Gfs*2 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- TCF12 | c.1884_1885insTGACT p.S629* | Nonsense Mutation (INS) | VAF 14/54 reads (26%) | called by mutect2, varscan2
- CD109 | c.1929T>C p.D643= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54645465; called by muse, mutect2, varscan2
- CNTLN | c.783G>A p.L261= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1250791035, COSV52066654; called by muse, mutect2, varscan2
- CWC25 | c.1146G>A p.R382= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as rs778053621; called by muse, mutect2
- DNAJC6 | c.1548T>G p.A516= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV54769921; called by muse, mutect2, varscan2
- ERCC1 | c.837T>A p.P279= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as COSV50003671; called by muse, mutect2, varscan2
- HIVEP2 | c.183A>G p.A61= | Silent (SNP) | VAF 30/242 reads (12%) | catalogued as COSV50005642; called by muse, mutect2, varscan2
- LILRA1 | c.1425C>T p.L475= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs776518350, COSV52177944; called by muse, mutect2
- UNC93A | c.1290C>T p.C430= | Silent (SNP) | VAF 38/446 reads (9%) | catalogued as rs769818090, COSV57806946; called by muse, mutect2
